Gene-level copy-number profile of tumor specimen TCGA-BC-A112-01A from TCGA case TCGA-BC-A112, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 80.8 years (29,511 days).
Specimen TCGA-BC-A112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7c42c982-321d-44ba-be13-8680b7e60c03.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A112-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4473a5e7-3f49-4206-824e-f2240c205fae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 855; copy number 2: 4,490; copy number 3: 22,324; copy number 4: 18,612; copy number 5: 8,265; copy number 6: 4,604; copy number 7: 458; copy number 8: 54; copy number 9: 45; copy number 10: 10; copy number 13: 41; copy number 14: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A112-01A-11D-A12Y-01): tumor purity 0.6, ploidy 3.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 662 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,924,740–155,602,197, 54 genes, copy number 14: PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1.
- chr1:163,769,339–164,899,296, 12 genes, copy number 7: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA.
- chr1:215,005,775–221,336,489, 78 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:237,042,184–248,919,946, 274 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:19,990,209–20,352,234, 12 genes, copy number 9: AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2.
- chr2:207,821,288–208,025,527, 1 gene, copy number 8 (within-gene range 4–8): PLEKHM3.
- chr2:208,019,638–208,146,158, 9 genes, copy number 8: RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB.
- chr5:165,905,126–168,264,157, 16 genes, copy number 7 (within-gene range 5–7): AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1.
- chr9:104,694,379–105,439,171, 10 genes, copy number 10: OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1.
- chr11:34,335,118–34,573,982, 7 genes, copy number 7: MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707.
- chr12:131,436,447–132,331,575, 44 genes, copy number 8: AC073578.4, AC073578.2, AC073578.5, AC073578.1, AC073578.3, AC140063.1, AC117500.5, AC117500.3, LINC02414, AC117500.6, AC117500.4, RNA5SP377, AC117500.1, RPS6P21, SFSWAP, AC117500.2, RNA5SP378, RNU6-1017P, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1.
- chr16:3,222,325–3,717,553, 33 genes, copy number 9 (within-gene range 5–9): ZNF200, MEFV, LINC00921, ZNF263, AJ003147.3, AC004232.2, TIGD7, ZNF75A, AC004232.1, AC025283.1, OR2C1, AC025283.2, MTCO1P28, MTND1P8, MTRNR2L4, ZSCAN32, ZNF174, ZNF597, NAA60, AC004224.2, MIR6126, C16orf90, AC004224.1, CLUAP1, AC004494.2, NLRC3, AC004494.1, AC006111.1, SLX4, DNASE1, AC006111.2, TRAP1, AC006111.3.
- chr16:68,209,442–68,448,508, 18 genes, copy number 7 (within-gene range 4–7): RPS12P27, AC020978.3, AC020978.7, AC020978.5, ESRP2, MIR6773, AC020978.4, PLA2G15, AC020978.2, SLC7A6, RNU6-1262P, SLC7A6OS, AC020978.9, PRMT7, AC020978.1, RNU4-30P, SMPD3, AC099521.2.
- chr17:51,630,313–54,771,277, 19 genes, copy number 7 (within-gene range 6–7): CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.
- chr17:82,047,902–82,650,657, 41 genes, copy number 13: RFNG, GPS1, DUS1L, FASN, CCDC57, AC129510.1, AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5.
- chr19:44,417,519–44,993,341, 34 genes, copy number 7 (within-gene range 5–7): ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1.

Autosomal genes at a single copy (total copy number 1): 855. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
